Somatic mutation profile of tumor specimen TCGA-CH-5741-01A (aliquot TCGA-CH-5741-01A-11D-1576-08) from TCGA case TCGA-CH-5741, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.8 years (20,759 days).
Specimen TCGA-CH-5741-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe2a23b9-05c0-4ef9-b04c-04030560abb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5741-10A (Blood Derived Normal), aliquot TCGA-CH-5741-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b80252b-bd17-4e96-9d90-cdba8d4f8517

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Intron 1, RNA 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG12 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs749744688, COSV57243330; called by muse, mutect2, varscan2
- CFAP300 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 18/237 reads (8%) | catalogued as COSV71570580, COSV71571017; called by muse, mutect2
- COL3A1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as rs778179067, COSV58597820; called by muse, mutect2, varscan2
- DLX5 | c.239T>A p.V80E | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.266); catalogued as rs149635296, COSV56034553; called by muse, mutect2, varscan2
- EML4 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV59306095; called by muse, mutect2, varscan2
- HELB | c.2770T>C p.Y924H | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56076563; called by muse, mutect2, varscan2
- MIP | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs774106797, COSV57508978; called by muse, varscan2
- PCDHA5 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV65350567, COSV65358851; called by muse, mutect2
- RBM12B | c.2151G>C p.Q717H | Missense Mutation (SNP) | VAF 158/416 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV67899049; called by muse, mutect2, varscan2
- SNAP25 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs774645750, COSV54776523; called by muse, mutect2, varscan2
- SULF1 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 19/370 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as rs894379479, COSV52695108; called by muse, mutect2
- TMEM260 | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs147042249; called by muse, mutect2
- TTC39C | c.953T>C p.M318T (on ENST00000317571 / NM_001135993.2; = p.M257T on NM_153211.4) | Missense Mutation (SNP) | VAF 81/132 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV58221608; called by muse, mutect2, varscan2
- TTN | c.1289T>A p.V430D | Missense Mutation (SNP) | VAF 11/246 reads (4%) | PolyPhen probably damaging (0.997); catalogued as COSV60392029; called by muse, mutect2
- XIRP1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200664748, COSV61141777; called by muse, mutect2, varscan2
- ZMYM3 | c.778+1G>T p.X260_splice | Splice Site (SNP) | VAF 72/89 reads (81%) | catalogued as COSV58741231; called by muse, mutect2, varscan2
- ADGRG2 | c.1465dup p.I489Nfs*10 (on ENST00000379869 / NM_001079858.3; = p.I486Nfs*10 on NM_005756.4) | Frame Shift Ins (INS) | VAF 74/117 reads (63%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.5916C>A p.S1972= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as COSV64143740; called by muse, mutect2, varscan2
- KCNIP4 | c.426C>T p.F142= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs751047200, COSV62845031; called by muse, mutect2, varscan2
- LILRB5 | c.495C>A p.T165= | Silent (SNP) | VAF 60/169 reads (36%) | catalogued as COSV60261530; called by muse, mutect2, varscan2
- RGS20 | c.180A>T p.A60= | Silent (SNP) | VAF 105/321 reads (33%) | catalogued as COSV52023063; called by muse, mutect2, varscan2
- SUN1 | c.659-1334A>G | Intron (SNP) | VAF 70/233 reads (30%) | catalogued as rs373167190; called by muse, mutect2, varscan2
- ZNF658B | n.1846C>T | RNA (SNP) | VAF 18/120 reads (15%) | called by mutect2, varscan2
